Gene-level copy-number profile of tumor specimen REBC-AC8U-TTP1-A from REBC case REBC-AC8U, project REBC-THYR (Comprehensive genomic characterization of radiation-related papillary thyroid cancer in the Ukraine). Sex at birth: male; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland.
Specimen REBC-AC8U-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c0837f85-4590-47f6-bbd1-f2f22941779c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator REBC-AC8U-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,713 have no estimate.
https://portal.gdc.cancer.gov/files/34ff0b62-5e1a-4c98-ba5b-06f588e116a1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 3,123; copy number 2: 55,638; copy number 3: 147.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:50,960,745–50,974,634, 1 gene: CDKN2C.
- chr3:12,328,003–12,328,274, 1 gene (within-gene range 0–2): AC091492.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 267. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
